Somatic mutation profile of tumor specimen TCGA-80-5611-01A (aliquot TCGA-80-5611-01A-01D-1625-08) from TCGA case TCGA-80-5611, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-80-5611-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58529771-2790-474a-8705-17d544e16999.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-80-5611-10A (Blood Derived Normal), aliquot TCGA-80-5611-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49670ab9-80b8-4ad1-bec3-5c591342abda

The open-access MAF lists 207 somatic variants for this specimen: 163 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 42, Frame Shift Del 7, Nonsense Mutation 7, Splice Site 3, 5'UTR 1, Splice Region 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.4379dup p.N1460Kfs*2 | Frame Shift Ins (INS) | VAF 32/50 reads (64%) | catalogued as rs387906455; ClinVar: pathogenic; called by mutect2, varscan2
- ACAN | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1162747201, COSV61357880; called by muse, mutect2, varscan2
- ACTN4 | c.2467A>T p.S823C | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV53148641; called by muse, mutect2, varscan2
- ADAMTS19 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV50772877, COSV99180042; called by muse, mutect2, varscan2
- ADCY3 | c.3023A>T p.E1008V | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as COSV53170561; called by muse, mutect2, varscan2
- ADPRH | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs150984649, COSV63695504; called by muse, mutect2, varscan2
- ANK1 | c.5560C>T p.P1854S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55889589; called by muse, mutect2, varscan2
- ANO4 | c.2617T>A p.Y873N (on ENST00000392977 / NM_001286615.2; = p.Y838N on NM_178826.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV54606282; called by muse, mutect2, varscan2
- ARHGAP35 | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101351823, COSV68333952; called by muse, mutect2, varscan2
- ASTN1 | c.2588G>C p.G863A | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56062335, COSV56078151; called by muse, mutect2, varscan2
- BMP2K | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.037); catalogued as COSV58597622; called by muse, mutect2, varscan2
- BMS1 | c.1276C>G p.R426G | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65734857; called by muse, mutect2, varscan2
- BRCA1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs80356991, CM014321, COSV58789313, COSV58795778; ClinVar: uncertain significance; called by muse, mutect2
- BTBD17 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV64730889; called by muse, mutect2
- C6orf118 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100025168; called by muse, mutect2, varscan2
- C7orf26 | c.541T>G p.F181V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV60419786; called by muse, mutect2, varscan2
- CACNA1H | c.6992G>A p.C2331Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV52356818; called by muse, mutect2
- CALU | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50823696; called by muse, mutect2, varscan2
- CBFA2T3 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV51930704; called by muse, mutect2, varscan2
- CCDC150 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV55876875; called by muse, mutect2, varscan2
- CDC37L1 | c.653A>G p.H218R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67866459; called by muse, mutect2, varscan2
- CDH16 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs748700773, COSV55338514; called by muse, mutect2, varscan2
- CHD6 | c.980A>C p.Y327S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58560168; called by muse, mutect2, varscan2
- CLK2 | c.312G>C p.E104D | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62877863; called by muse, mutect2, varscan2
- CNKSR1 | c.931G>A p.A311T (on ENST00000374253 / NM_001297647.2; = p.A304T on NM_006314.3) | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV64163868; called by muse, mutect2, varscan2
- COL12A1 | c.6408G>T p.W2136C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59402817; called by muse, mutect2, varscan2
- COL25A1 | c.1370A>G p.Q457R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.632); catalogued as COSV67655217; called by muse, mutect2, varscan2
- COL27A1 | c.3250-1G>T p.X1084_splice | Splice Site (SNP) | VAF 17/77 reads (22%) | catalogued as COSV61929194; called by muse, mutect2, varscan2
- COL6A1 | c.344G>C p.S115T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.457); catalogued as rs372627181, COSV62614659; called by muse, mutect2, varscan2
- COPB1 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51449827; called by muse, mutect2
- COQ6 | c.1049T>A p.L350* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV53179635; called by muse, mutect2, varscan2
- CSMD3 | c.7356T>A p.C2452* (on ENST00000297405 / NM_001363185.1; = p.C2348* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV52260871; called by muse, mutect2, varscan2
- DCDC1 | c.3826C>A p.H1276N (on ENST00000597505 / NM_001367979.1; = p.H383N on NM_020869.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV58001492; called by muse, mutect2, varscan2
- DDX60L | c.2060G>A p.G687D | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52718695; called by muse, mutect2
- DGKI | c.546G>C p.E182D | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV55965922; called by muse, mutect2, varscan2
- DMBT1 | c.367T>G p.W123G | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57553098; called by muse, mutect2, varscan2
- DMXL1 | c.4971-1G>T p.X1657_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV60717896; called by muse, mutect2, varscan2
- DNAH11 | c.11266C>G p.R3756G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs766141716, COSV60969994, COSV60978211; called by muse, mutect2, varscan2
- DNAJC6 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV54779198; called by muse, mutect2, varscan2
- DSPP | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as COSV56813834; called by muse, mutect2, varscan2
- DUSP8 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100524535, COSV59030896; called by muse, mutect2
- DYNC2H1 | c.7298C>G p.P2433R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100518500, COSV62101371; called by muse, mutect2, varscan2
- EHBP1 | c.2377A>G p.R793G | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as rs924297516, COSV50429067; called by muse, mutect2
- ELOVL3 | c.714G>C p.W238C | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV64174790; called by muse, mutect2, varscan2
- EPG5 | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56356862; called by muse, mutect2, varscan2
- EYA4 | c.88A>G p.M30V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs1026869914, COSV62057812; called by muse, mutect2, varscan2
- FAM3C | c.467A>T p.K156I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63436181; called by muse, mutect2, varscan2
- FBXL7 | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV61654331; called by muse, mutect2, varscan2
- FGFBP2 | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52588679; called by muse, mutect2, varscan2
- FN1 | c.3442G>T p.E1148* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV60559387; called by muse, mutect2, varscan2
- FOXI1 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60389462; called by muse, mutect2, varscan2
- FRAS1 | c.4361T>A p.I1454N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53631565; called by muse, mutect2, varscan2
- FSCB | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 49/198 reads (25%) | catalogued as COSV100469892; called by muse, mutect2, varscan2
- FSCB | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100469901; called by muse, mutect2, varscan2
- GABRA2 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734122, COSV62917520; called by muse, mutect2, varscan2
- GALNT10 | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51731183; called by muse, mutect2
- GCNA | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV65467719; called by muse, mutect2, varscan2
- H2AC17 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs1251694908, COSV58154185; called by muse, mutect2, varscan2
- H3C10 | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60798927; called by muse, mutect2, varscan2
- HAO2 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58041321; called by muse, mutect2, varscan2
- HDX | c.659G>T p.C220F | Missense Mutation (SNP) | VAF 70/105 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV52980864; called by muse, mutect2, varscan2
- HK3 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV52842873; called by muse, mutect2
- IGHG4 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as rs375787463; called by muse, mutect2, varscan2
- INTS12 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV60863090; called by muse, mutect2, varscan2
- ITIH5 | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs532165971, COSV53675251; called by muse, mutect2, varscan2
- JPH3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772099172, COSV52471657; called by muse, mutect2, varscan2
- KARS1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555512883, COSV56693537; ClinVar: uncertain significance; called by muse, mutect2
- KCNU1 | c.2837G>A p.G946D | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV67758432; called by muse, mutect2, varscan2
- KLK2 | c.553G>C p.A185P | Missense Mutation (SNP) | VAF 83/119 reads (70%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.719); catalogued as COSV57570363; called by muse, mutect2, varscan2
- KRT15 | c.520A>C p.N174H | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54181032; called by muse, mutect2, varscan2
- LAMA5 | c.10616C>T p.T3539I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs750851515, COSV53366885; called by muse, mutect2, varscan2
- LMTK3 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54317818; called by muse, mutect2, varscan2
- LRRC7 | c.2156G>A p.S719N (on ENST00000651989 / NM_001370785.2; = p.S686N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV50540396, COSV99229915; called by muse, mutect2, varscan2
- LRRTM4 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV69139321, COSV69141180; called by muse, mutect2, varscan2
- LYST | c.2956G>A p.G986S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.958); catalogued as COSV67711113; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1301A>C p.K434T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51724279; called by muse, mutect2, varscan2
- MARK3 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53513931; called by muse, mutect2, varscan2
- MFSD12 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.044); catalogued as rs1398655384, COSV62598215; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1949T>C p.L650S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54915928; called by muse, mutect2, varscan2
- MYO7A | c.6458C>T p.P2153L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60021394; called by muse, mutect2, varscan2
- NEK8 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV52047367; called by muse, mutect2
- NLRP7 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.714); catalogued as COSV60178638; called by muse, mutect2, varscan2
- NR1D1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as rs374973486; called by muse, mutect2, varscan2
- NRXN3 | c.2357A>G p.K786R (on ENST00000335750 / NM_001330195.2; = p.K413R on NM_004796.6) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV59782489; called by muse, mutect2, varscan2
- NSD1 | c.2105C>A p.P702H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV61770738; called by muse, mutect2, varscan2
- OR10C1 | c.364G>A p.D122N (on ENST00000622521; = p.D120N on NM_013941.3) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV65823629; called by muse, mutect2
- OR13C3 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.109); catalogued as COSV101053239, COSV66166083; called by muse, mutect2, varscan2
- OR13C5 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as COSV66165099; called by muse, mutect2, varscan2
- OR4D5 | c.153del p.D52Tfs*47 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as COSV58306366, COSV58307167; called by mutect2, pindel, varscan2
- OR52E2 | c.315del p.F105Lfs*41 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV100384881; called by mutect2, pindel, varscan2
- OR5B17 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100641972, COSV62159848; called by muse, mutect2
- OR5D14 | c.754A>T p.I252F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV59457590; called by muse, mutect2
- OSBPL10 | c.497T>G p.L166R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67342390; called by muse, mutect2, varscan2
- P2RX5 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56593207; called by muse, mutect2, varscan2
- PARD3 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60756684; called by muse, mutect2, varscan2
- PBXIP1 | c.874C>G p.Q292E | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63777511; called by muse, mutect2
- PCDHA4 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV63544412; called by muse, mutect2, varscan2
- PCDHB1 | c.1393A>C p.N465H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60632385; called by muse, mutect2, varscan2
- PCNX4 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1566931650, COSV100470825; called by muse, mutect2, varscan2
- PDE3B | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV56387807; called by muse, mutect2, varscan2
- PHKG2 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100079739, COSV60313128; called by muse, mutect2, varscan2
- PID1 | c.740C>T p.S247F (on ENST00000354069 / NM_001330156.1; = p.S245F on NM_017933.5) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100819716, COSV62479684; called by muse, mutect2, varscan2
- PIK3CB | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56688500; called by mutect2, varscan2
- PIKFYVE | c.5861G>T p.G1954V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52246096; called by muse, mutect2, varscan2
- PLCH1 | c.3221G>T p.C1074F (on ENST00000340059 / NM_001130960.2; = p.C1066F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV58205703; called by muse, mutect2, varscan2
- PPP1R8 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV52580767; called by muse, mutect2, varscan2
- PREPL | c.80A>T p.H27L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as COSV53218300; called by muse, mutect2, varscan2
- PRRC2C | c.2611G>A p.A871T (on ENST00000367742; = p.A869T on NM_015172.4) | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58909969; called by muse, mutect2, varscan2
- PSG9 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV52486768; called by muse, mutect2, varscan2
- PYHIN1 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV63723455; called by muse, mutect2
- RAB11FIP3 | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV51936264; called by muse, mutect2, varscan2
- RAB3IP | c.152C>T p.T51I (on ENST00000550536 / NM_175623.4; = p.T35I on NM_022456.5) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1448321312, COSV56085426; called by muse, mutect2, varscan2
- RACK1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV65175016; called by muse, mutect2, varscan2
- RARA | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54190936, COSV54197865; called by muse, mutect2, varscan2
- RBM46 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs771879035, COSV55980735; called by muse, mutect2, varscan2
- RIF1 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV54621304; called by muse, mutect2, varscan2
- RPS6KA2 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55826124; called by muse, mutect2, varscan2
- RRP9 | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51755681; called by muse, mutect2, varscan2
- RXYLT1 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV54169369; called by muse, mutect2, varscan2
- SAMD9 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV66074746; called by muse, mutect2, varscan2
- SATB2 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV53489754; called by muse, mutect2, varscan2
- SBNO1 | c.2849C>G p.A950G (on ENST00000420886; = p.A949G on NM_018183.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV57344263; called by muse, mutect2
- SCN1A | c.5521C>A p.L1841M (on ENST00000303395 / NM_001202435.3; = p.L1830M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV57680347; called by muse, mutect2, varscan2
- SEC24C | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59541830, COSV59543775; called by muse, mutect2, varscan2
- SEMA5A | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66801148; called by muse, mutect2, varscan2
- SETD7 | c.607A>T p.T203S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV56802328, COSV56802559; called by muse, mutect2, varscan2
- SIPA1L2 | c.5044C>A p.L1682I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53384001, COSV53395773; called by muse, mutect2, varscan2
- SLITRK2 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV59427518; called by muse, mutect2, varscan2
- SMARCA4 | c.2011G>T p.E671* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV60811003; called by muse, mutect2, varscan2
- SMYD1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs200376153; called by muse, mutect2, varscan2
- SPTA1 | c.3023G>T p.S1008I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63760786; called by muse, mutect2, varscan2
- SRCAP | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970002773, COSV52677778; called by muse, mutect2, varscan2
- ST6GAL2 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 38/195 reads (19%) | PolyPhen benign (0.001); catalogued as COSV64530417; called by muse, mutect2, varscan2
- TBC1D22B | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV65143215; called by muse, mutect2
- TEX2 | c.1936A>T p.M646L | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV51983988; called by muse, mutect2, varscan2
- TFAP2C | c.44G>C p.C15S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52372523; called by muse, mutect2
- TIFAB | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV72345880; called by muse, mutect2, varscan2
- TM9SF2 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV64507187; called by muse, mutect2, varscan2
- TMX4 | c.742A>C p.K248Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV55681825, COSV55682323; called by muse, mutect2, varscan2
- TTBK1 | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs769742230, COSV52494581; called by muse, mutect2, varscan2
- TTN | c.22317T>A p.D7439E (on ENST00000591111; = p.D6512E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | PolyPhen benign (0.051); catalogued as COSV100616075, COSV60225280; called by muse, mutect2, varscan2
- TTN | c.14846G>T p.R4949L (on ENST00000591111; = p.R4022L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/199 reads (20%) | PolyPhen benign (0.272); catalogued as COSV60159275, COSV60225292; called by muse, mutect2, varscan2
- TYW1 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761345069, COSV62754576; called by muse, mutect2, varscan2
- UBR2 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV65751584; called by muse, mutect2, varscan2
- UGT1A6 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV59394657; called by muse, mutect2, varscan2
- VWA8 | c.1237A>G p.S413G | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1566486561, COSV55701597; called by muse, mutect2, varscan2
- WDR62 | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); catalogued as rs1177663116, COSV54331874; called by muse, mutect2, varscan2
- ZC3H10 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778584199, COSV57769164; called by muse, mutect2, varscan2
- ZEB2 | c.1761A>T p.K587N | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV57962185; called by muse, mutect2, varscan2
- ZNF16 | c.1675A>G p.T559A | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.675); catalogued as COSV52764935, COSV52765780; called by muse, mutect2, varscan2
- ZNF343 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53854971; called by muse, mutect2, varscan2
- ZNF711 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV52157104; called by muse, mutect2, varscan2
- ZNF99 | c.129G>A p.L43= | Splice Region (SNP) | VAF 22/87 reads (25%) | catalogued as COSV68056209, COSV99078016; called by muse, mutect2, varscan2
- AP5B1 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- C6orf118 | c.1181del p.K394Rfs*40 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- CCL18 | c.43A>G p.M15V | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHIPL1 | c.536_537delinsC p.K179Tfs*55 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | called by pindel, varscan2*
- IGKV1D-43 | c.118A>T p.R40* | Nonsense Mutation (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- MUC2 | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); called by muse, mutect2
- SPHK2 | c.757-2_772del p.X253_splice | Splice Site (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- SPTA1 | c.2704del p.Q902Sfs*21 | Frame Shift Del (DEL) | VAF 42/249 reads (17%) | called by mutect2, pindel, varscan2
- TGFBRAP1 | c.162del p.R54Sfs*26 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- UNC13C | c.4607del p.P1536Qfs*7 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- ADGRL3 | c.3435A>T p.I1145= (on ENST00000506720 / NM_001322402.2; = p.I1077= on NM_015236.6) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV72231401; called by muse, mutect2, varscan2
- AHNAK2 | c.11037G>T p.G3679= | Silent (SNP) | VAF 69/214 reads (32%) | catalogued as COSV60923850; called by muse, mutect2, varscan2
- AP5B1 | c.1143G>T p.L381= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- ATP10B | c.1719C>A p.S573= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV59160365; called by muse, mutect2, varscan2
- BBS2 | c.87G>T p.P29= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV55329063; called by muse, mutect2, varscan2
- BRWD3 | c.441C>A p.T147= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100956554; called by muse, mutect2, varscan2
- C11orf49 | c.666T>A p.L222= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV53568910; called by muse, mutect2, varscan2
- CAMTA1 | c.2874C>A p.P958= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs780673433, COSV57916838; called by muse, mutect2, varscan2
- CCT3 | c.486C>G p.T162= | Silent (SNP) | VAF 46/183 reads (25%) | catalogued as COSV55290512; called by muse, mutect2, varscan2
- CNDP2 | c.810G>T p.T270= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100159205, COSV60840902; called by muse, mutect2, varscan2
- DSP | c.2106C>A p.I702= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV65794376; called by muse, mutect2, varscan2
- F7 | c.1080C>A p.L360= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV60647239; called by muse, mutect2, varscan2
- FAT4 | c.8316C>T p.A2772= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as COSV58699677; called by muse, mutect2
- FER1L6 | c.4629T>C p.C1543= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV67551820; called by muse, mutect2, varscan2
- GUCY1A2 | c.2031G>T p.R677= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV56495446; called by muse, mutect2, varscan2
- HFM1 | c.600A>G p.K200= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV54033545; called by muse, mutect2, varscan2
- HPS4 | c.87A>G p.E29= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV53227146; called by muse, mutect2, varscan2
- KLHL15 | c.1746G>T p.L582= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV60141453; called by muse, mutect2, varscan2
- MB21D2 | c.145C>A p.R49= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1360839243, COSV66665045; called by muse, mutect2, varscan2
- MYO18A | c.3966T>A p.A1322= | Silent (SNP) | VAF 78/299 reads (26%) | catalogued as COSV62870916; called by muse, mutect2, varscan2
- NAGS | c.537C>T p.A179= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs915859475, COSV53228584; called by muse, mutect2, varscan2
- NKX2-2 | c.63C>G p.T21= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV65820026; called by muse, mutect2, varscan2
- OR4A15 | c.60G>A p.E20= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs778287590, COSV59036581; called by muse, mutect2, varscan2
- OTX2 | c.867G>A p.L289= (on ENST00000408990 / NM_172337.3; = p.L297= on NM_021728.4) | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV59766951; called by muse, mutect2, varscan2
- PHACTR4 | c.1782A>G p.T594= (on ENST00000373839 / NM_001350159.2; = p.T604= on NM_023923.4) | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100868487, COSV65784764; called by muse, mutect2, varscan2
- PHC2 | c.942T>A p.V314= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as COSV57106517; called by muse, mutect2, varscan2
- PHF12 | c.1545A>T p.P515= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as COSV52020961; called by muse, mutect2, varscan2
- PIWIL3 | c.666A>G p.L222= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs374800363; called by muse, mutect2, varscan2
- PLEKHG3 | c.2322G>A p.K774= (on ENST00000394691; = p.K830= on NM_001308147.2) | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs1007830465, COSV55982166; called by muse, mutect2, varscan2
- PNPLA6 | c.3318G>T p.L1106= (on ENST00000414982 / NM_001166111.2; = p.L1058= on NM_006702.5) | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV55382519; called by muse, mutect2, varscan2
- PPEF2 | c.1413G>T p.V471= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV54424884; called by muse, mutect2, varscan2
- RAPGEF1 | c.2679C>T p.V893= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs754238627, COSV64701171; called by muse, mutect2, varscan2
- RLN2 | c.537A>G p.R179= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV57731635; called by muse, mutect2, varscan2
- THADA | c.2712A>G p.V904= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV57689387; called by muse, mutect2, varscan2
- TLR2 | c.2088C>T p.S696= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as COSV52607443; called by muse, mutect2, varscan2
- TMCC1 | c.1863G>T p.T621= (on ENST00000393238 / NM_001349268.2; = p.T297= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV61442023; called by muse, mutect2, varscan2
- TMEM192 | c.483C>T p.F161= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1426566950, COSV60585802; called by muse, mutect2, varscan2
- USP36 | c.627G>T p.A209= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV61754871; called by muse, mutect2, varscan2
- ZNF330 | c.555A>G p.S185= | Silent (SNP) | VAF 15/228 reads (7%) | catalogued as COSV53708000; called by muse, mutect2
- ZNF337 | c.18C>A p.A6= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV53322516; called by muse, mutect2, varscan2
- ZNF791 | c.1569C>G p.P523= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV58483102; called by muse, mutect2, varscan2
- ZNF875 | c.255G>A p.L85= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs377264603; called by muse, mutect2, varscan2
- GLYATL1 | c.-92G>A | 5'UTR (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100265573; called by muse, mutect2, varscan2
- PRND | chr20:4732488 G>C | 3'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
